Somatic mutation profile of tumor specimen TARGET-20-PASLSI-09A (aliquot TARGET-20-PASLSI-09A-01D) from TARGET case TARGET-20-PASLSI, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.2 years (3,713 days).
Specimen TARGET-20-PASLSI-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8ad2eed-d0f5-43ab-815f-9b43d4cdaae0.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASLSI-14A (Bone Marrow Normal), aliquot TARGET-20-PASLSI-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b062c7e2-336b-4d4d-87b0-7dd532468fee

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.2459A>G p.D820G | Missense Mutation (SNP) | VAF 27/124 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913682, COSV55387023, COSV55391660, COSV55405326; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FAT1 | c.10478C>T p.P3493L | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as rs200357548; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIT | c.1255_1257del p.D419del | In Frame Del (DEL) | VAF 14/110 reads (13%) | called by mutect2, pindel, varscan2
